Somatic mutation profile of tumor specimen TCGA-85-8584-01A (aliquot TCGA-85-8584-01A-11D-2395-08) from TCGA case TCGA-85-8584, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary squamous cell carcinoma; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 71.4 years (26,081 days).
Specimen TCGA-85-8584-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0ee82263-cf61-4cab-910d-af25fc7a23a3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-8584-10A (Blood Derived Normal), aliquot TCGA-85-8584-10A-01D-2395-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f8692b9-2463-4804-9e72-b917e9c14016

The open-access MAF lists 274 somatic variants for this specimen: 206 protein-altering or splice-affecting, 62 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 169, Silent 62, Nonsense Mutation 17, Frame Shift Del 9, Splice Site 6, Intron 3, Frame Shift Ins 2, RNA 2, Splice Region 2, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011462.1 | c.144G>T p.Q48H | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.466); catalogued as COSV100641067; called by muse, mutect2
- ADAM18 | c.887G>T p.S296I | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV99696228; called by muse, mutect2, varscan2
- ADAMTS14 | c.2254C>G p.H752D | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs770129503, COSV100941933; called by muse, mutect2, varscan2
- ADAMTS16 | c.942C>A p.Y314* | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | catalogued as COSV56989490, COSV99943452; called by muse, mutect2, varscan2
- ADGRB2 | c.3885C>A p.F1295L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99927120; called by muse, mutect2, varscan2
- ADGRF4 | c.2050C>A p.P684T | Missense Mutation (SNP) | VAF 62/213 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV99349166; called by muse, mutect2, varscan2
- AHNAK2 | c.2780C>T p.P927L | Missense Mutation (SNP) | VAF 71/467 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100319234; called by muse, mutect2, varscan2
- ANK1 | c.4463G>A p.R1488Q | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.116); catalogued as rs763866388, COSV55901132; called by muse, mutect2, varscan2
- ANK3 | c.8857G>T p.E2953* | Nonsense Mutation (SNP) | VAF 28/118 reads (24%) | catalogued as COSV99782929; called by muse, mutect2, varscan2
- ANKRD26 | c.4009G>T p.E1337* | Nonsense Mutation (SNP) | VAF 11/67 reads (16%) | catalogued as rs1041303008, COSV101063488; called by muse, mutect2, varscan2
- ANKRD26 | c.4008G>T p.M1336I | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV101063491; called by muse, mutect2, varscan2
- ANKRD55 | c.1418G>C p.S473T | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.732); catalogued as rs1269521540, COSV100591748, COSV61947482; called by muse, mutect2, varscan2
- APPL2 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 118/177 reads (67%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.024); catalogued as COSV99315214; called by muse, mutect2, varscan2
- ARHGEF4 | c.230A>T p.K77M | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as COSV100388888; called by muse, mutect2, varscan2
- ARSK | c.1333G>T p.D445Y | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101187603; called by muse, mutect2
- AZIN2 | c.287T>A p.M96K | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99613904; called by muse, mutect2, varscan2
- B4GALNT4 | c.2817C>A p.F939L | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as COSV100327928; called by muse, mutect2, varscan2
- BHMT | c.65T>A p.I22N | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV99165568; called by muse, mutect2, varscan2
- BOD1L1 | c.6761G>T p.G2254V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99240594; called by muse, mutect2
- BRSK1 | c.1172G>T p.G391V | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs758425269, COSV100474753, COSV58669292; called by muse, mutect2, varscan2
- C1QTNF5 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.187); catalogued as COSV100264973; called by muse, mutect2, varscan2
- C3 | c.4881G>T p.W1627C | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99837422; called by muse, mutect2, varscan2
- C5orf15 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99198363; called by muse, mutect2, varscan2
- C6orf118 | c.446T>C p.V149A | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.079); catalogued as COSV100025304; called by muse, mutect2, varscan2
- CAMK2G | c.1609C>T p.R537C (on ENST00000423381 / NM_001367518.1; = p.R474C on NM_001222.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV99990488; called by muse, mutect2, varscan2
- CARD11 | c.2990G>A p.G997D | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.493); catalogued as rs1334146426, COSV101211075; called by muse, mutect2, varscan2
- CARD9 | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 14/54 reads (26%) | catalogued as COSV59997108; called by muse, mutect2, varscan2
- CASP5 | c.1256T>A p.I419K | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99508198; called by muse, mutect2, varscan2
- CBX6 | c.808G>T p.A270S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV99328311; called by muse, mutect2, varscan2
- CCDC113 | c.602A>T p.K201I | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99541283; called by muse, mutect2, varscan2
- CCDC30 | c.1219G>C p.E407Q (on ENST00000340612; = p.E364Q on NM_001080850.3) | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV100501777; called by muse, mutect2
- CCDC74A | c.544+2T>C p.X182_splice | Splice Site (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99723976; called by muse, mutect2, varscan2
- CCNG2 | c.353A>G p.N118S | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.257); catalogued as COSV100313386; called by muse, mutect2, varscan2
- CCR6 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100551225; called by muse, mutect2, varscan2
- CD226 | c.683C>A p.A228E | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.187); catalogued as COSV99711621; called by muse, mutect2, varscan2
- CD300LB | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.045); catalogued as COSV100075631; called by muse, mutect2, varscan2
- CD8B | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.282); catalogued as rs967089228, COSV100514798; called by muse, mutect2, varscan2
- CEACAM21 | c.438G>T p.Q146H | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99494937; called by muse, mutect2, varscan2
- CEP135 | c.109T>C p.F37L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201621075, COSV99954971; called by muse, mutect2, varscan2
- CLDN22 | c.595T>A p.Y199N | Missense Mutation (SNP) | VAF 44/298 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.669); catalogued as COSV100033053; called by muse, mutect2, varscan2
- CNTNAP2 | c.631G>T p.V211F | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as COSV62271176; called by muse, mutect2, varscan2
- COL2A1 | c.724C>A p.R242S | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.369); catalogued as CD103304, COSV100477780; called by muse, mutect2, varscan2
- CPXM1 | c.1739A>T p.Y580F | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101013860; called by muse, mutect2, varscan2
- CRYBA1 | c.452T>C p.M151T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs1567671690, COSV99837094; called by muse, mutect2, varscan2
- CSF2RA | c.239C>G p.S80W | Missense Mutation (SNP) | VAF 46/323 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.821); catalogued as rs201854740, COSV100818008, COSV62623853; called by muse, mutect2, varscan2
- CSMD1 | c.6068A>T p.E2023V (on ENST00000520002; = p.E2022V on NM_033225.6) | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100154854; called by muse, mutect2, varscan2
- CSMD3 | c.8603C>A p.P2868Q (on ENST00000297405 / NM_001363185.1; = p.P2699Q on NM_052900.3) | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52232638; called by muse, mutect2, varscan2
- CSMD3 | c.5956A>T p.T1986S (on ENST00000297405 / NM_001363185.1; = p.T1882S on NM_052900.3) | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV99851158; called by muse, mutect2, varscan2
- CTAGE1 | c.1865G>T p.G622V | Missense Mutation (SNP) | VAF 29/215 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV101194726; called by muse, mutect2, varscan2
- CYTIP | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99938969; called by muse, mutect2, varscan2
- DEPDC7 | c.961T>A p.S321T (on ENST00000241051 / NM_001077242.2; = p.S312T on NM_139160.2) | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as rs776124820, COSV99572959; called by muse, mutect2, varscan2
- DLGAP3 | c.2506G>T p.A836S | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99333300; called by muse, mutect2, varscan2
- DNAH11 | c.4972G>A p.D1658N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749120592, COSV60950030; called by muse, mutect2, varscan2
- DNAH3 | c.2457G>C p.K819N | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV54509080, COSV99771271; called by muse, mutect2, varscan2
- DNAH9 | c.7665C>A p.Y2555* | Nonsense Mutation (SNP) | VAF 8/49 reads (16%) | catalogued as COSV99308767; called by muse, mutect2, varscan2
- DNER | c.1992C>G p.I664M | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs546911349, COSV100520285; called by muse, mutect2, varscan2
- DPYSL3 | c.429C>A p.H143Q | Missense Mutation (SNP) | VAF 41/253 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100575442; called by muse, mutect2, varscan2
- ENAM | c.2014G>A p.G672S | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.668); catalogued as COSV101253382; called by muse, mutect2, varscan2
- FABP12 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100846588; called by muse, mutect2
- FAM217B | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV100674705; called by muse, mutect2, varscan2
- FAM221A | c.321G>T p.Q107H | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV100794399; called by muse, mutect2, varscan2
- FARP2 | c.11T>C p.I4T | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.963); catalogued as COSV99885760; called by muse, mutect2, varscan2
- FAT1 | c.1795C>G p.L599V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV101499687; called by muse, mutect2, varscan2
- FNIP2 | c.2551G>T p.E851* | Nonsense Mutation (SNP) | VAF 22/103 reads (21%) | catalogued as COSV100033397; called by muse, mutect2, varscan2
- FRMPD4 | c.1525G>T p.A509S | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as COSV101044286; called by muse, mutect2, varscan2
- FSHR | c.172C>A p.L58I | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV100438320, COSV58627762; called by muse, mutect2, varscan2
- GAB1 | c.932del p.P311Qfs*24 | Frame Shift Del (DEL) | VAF 20/105 reads (19%) | catalogued as COSV53756111; called by mutect2, pindel, varscan2
- GBE1 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.075); catalogued as COSV101450371; called by muse, mutect2
- GCN1 | c.3312G>A p.R1104= | Splice Region (SNP) | VAF 9/59 reads (15%) | catalogued as COSV100326224; called by muse, mutect2, varscan2
- GCNT2 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs763720351, COSV101097748; called by muse, mutect2, varscan2
- GIMAP8 | c.24G>A p.M8I | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs372078848, COSV56234599; called by muse, mutect2, varscan2
- GLI1 | c.2713C>G p.Q905E | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs760909851, COSV57364174; called by muse, mutect2, varscan2
- GPAM | c.2122-1G>A p.X708_splice | Splice Site (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100788480; called by mutect2, varscan2
- GPR37 | c.556G>C p.A186P | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs774582817, COSV58255960; called by muse, mutect2, varscan2
- GPR39 | c.837G>T p.R279S | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV100258816; called by muse, mutect2, varscan2
- GTF2H1 | c.1143-2A>G p.X381_splice | Splice Site (SNP) | VAF 37/186 reads (20%) | catalogued as COSV99786689; called by muse, mutect2, varscan2
- GTF3C2 | c.1016T>A p.L339* | Nonsense Mutation (SNP) | VAF 15/68 reads (22%) | catalogued as COSV99273401; called by muse, mutect2, varscan2
- H3C1 | c.379C>G p.L127V | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV55119244, COSV99772173, COSV99772224; called by muse, mutect2, varscan2
- HACL1 | c.313T>G p.L105V | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.173); catalogued as COSV100337428; called by muse, mutect2, varscan2
- HAP1 | c.1988G>T p.R663L (on ENST00000310778 / NM_001367460.1; = p.R611L on NM_177977.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV100170096; called by muse, mutect2, varscan2
- HDGFL1 | c.17T>A p.M6K | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100014765; called by muse, mutect2, varscan2
- HECTD1 | c.3494A>T p.N1165I | Missense Mutation (SNP) | VAF 15/138 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101237565; called by muse, mutect2, varscan2
- HEPACAM2 | c.1229G>A p.G410E (on ENST00000394468 / NM_001039372.4; = p.G398E on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59059997; called by muse, mutect2, varscan2
- HSPA4L | c.1553T>G p.F518C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1266325500, COSV99613842; called by muse, mutect2, varscan2
- HYOU1 | c.1832G>A p.G611E | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.129); catalogued as rs562490154, COSV101345704; called by muse, mutect2, varscan2
- IL17RD | c.1284C>G p.Y428* | Nonsense Mutation (SNP) | VAF 37/176 reads (21%) | catalogued as COSV99578472; called by muse, mutect2, varscan2
- ITGA2 | c.2317G>T p.A773S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.77); PolyPhen benign (0.13); catalogued as rs144380292; called by muse, mutect2, varscan2
- KCNT1 | c.3291G>T p.Q1097H (on ENST00000488444; = p.Q1123H on NM_020822.3) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV99706993; called by muse, mutect2
- KEAP1 | c.1786del p.R596Efs*2 | Frame Shift Del (DEL) | VAF 25/150 reads (17%) | catalogued as COSV50669090; called by mutect2, pindel, varscan2
- KLHL36 | c.1534G>T p.D512Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50718743, COSV99257174; called by muse, mutect2, varscan2
- KRT20 | c.58G>T p.V20L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99391643; called by muse, mutect2, varscan2
- LCE1E | c.212G>C p.G71A | Missense Mutation (SNP) | VAF 36/170 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs150074891; called by muse, varscan2
- LCLAT1 | c.240C>G p.I80M | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV100093326; called by muse, mutect2, varscan2
- LCT | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs935973362, COSV51551444, COSV99930659; called by muse, mutect2, varscan2
- LILRA1 | c.923C>A p.S308* | Nonsense Mutation (SNP) | VAF 15/184 reads (8%) | catalogued as COSV52178552; called by muse, mutect2
- LRFN5 | c.110G>T p.C37F | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53246461; called by muse, mutect2, varscan2
- LRRC23 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 76/129 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1555139380, COSV99145390; called by muse, mutect2, varscan2
- MARCHF10 | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.045); catalogued as COSV100248715; called by muse, mutect2, varscan2
- MC4R | c.992G>C p.R331T | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); catalogued as COSV100236164; called by muse, mutect2, varscan2
- MED13 | c.2214A>T p.L738F | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.991); catalogued as rs770918080, COSV101181512; called by muse, mutect2, varscan2
- MED13L | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99930463; called by muse, mutect2, varscan2
- MED13L | c.1630C>A p.P544T | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56115756, COSV99930465; called by muse, mutect2, varscan2
- MEGF6 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750313582, COSV99621567; called by muse, mutect2, varscan2
- MUC16 | c.4247C>A p.P1416H | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as rs1486438899, COSV101202122, COSV67494439; called by muse, mutect2, varscan2
- MUC16 | c.4246C>A p.P1416T | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.387); catalogued as COSV101202123; called by muse, mutect2, varscan2
- MUC16 | c.563A>G p.K188R | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV101202124; called by muse, mutect2, varscan2
- MX2 | c.655C>A p.P219T | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100416258, COSV58095510; called by muse, mutect2, varscan2
- MYADM | c.218G>A p.C73Y | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100425252; called by muse, mutect2, varscan2
- MYH11 | c.2911C>A p.L971I | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.259); catalogued as COSV100260527; called by muse, mutect2, varscan2
- MYH2 | c.2125C>T p.R709C | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs761461325, COSV55443801; called by muse, mutect2, varscan2
- NAV3 | c.247T>A p.Y83N | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57083172, COSV99896687; called by muse, mutect2, varscan2
- NEUROD1 | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as rs1559135426, COSV54548947, COSV99717089; called by muse, mutect2, varscan2
- NEUROG1 | c.634C>A p.P212T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV100130877, COSV100130878; called by muse, mutect2, varscan2
- NF1 | c.4813A>G p.I1605V (on ENST00000358273 / NM_001042492.3; = p.I1584V on NM_000267.3) | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs199474766, CM000808, COSV100648496; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NKAIN2 | c.55-1G>T p.X19_splice | Splice Site (SNP) | VAF 30/155 reads (19%) | catalogued as COSV100864485; called by muse, mutect2, varscan2
- NKAIN2 | c.55G>T p.V19F | Missense Mutation (SNP) | VAF 30/156 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV100864487; called by muse, mutect2, varscan2
- NRAP | c.49G>T p.E17* | Nonsense Mutation (SNP) | VAF 17/109 reads (16%) | catalogued as rs576211641, COSV100748663, COSV63489092; called by muse, mutect2, varscan2
- NRXN2 | c.1215C>A p.D405E | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99636335; called by muse, mutect2, varscan2
- NT5C1B | c.1217G>T p.R406L (on ENST00000359846 / NM_001199086.2; = p.R346L on NM_033253.4) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100410341; called by muse, mutect2, varscan2
- NUP93 | c.1245G>T p.W415C | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100360579; called by muse, mutect2, varscan2
- OBSL1 | c.1837G>T p.V613L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99217661; called by muse, mutect2, varscan2
- OPRPN | c.317A>G p.H106R | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.136); catalogued as COSV101271111; called by muse, mutect2, varscan2
- OR10C1 | c.616C>T p.L206F (on ENST00000622521; = p.L204F on NM_013941.3) | Missense Mutation (SNP) | VAF 78/304 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.075); catalogued as rs767606689, COSV101010898; called by muse, mutect2, varscan2
- OR10Q1 | c.722G>T p.R241L | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as COSV100372415; called by muse, mutect2, varscan2
- OR2D3 | c.441C>A p.Y147* | Nonsense Mutation (SNP) | VAF 34/142 reads (24%) | catalogued as COSV99550027; called by muse, mutect2, varscan2
- OR2T10 | c.412C>A p.H138N | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as COSV100393843; called by muse, mutect2, varscan2
- OR4C15 | c.265G>T p.A89S (on ENST00000314644; = p.A35S on NM_001001920.2) | Missense Mutation (SNP) | VAF 30/185 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.792); catalogued as COSV100116185, COSV58954667; called by muse, mutect2, varscan2
- OR5B2 | c.235G>C p.V79L | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as COSV100223020; called by muse, mutect2, varscan2
- OR8D1 | c.851T>A p.M284K | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV100766685; called by muse, mutect2
- OR8J1 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.595); catalogued as COSV100274998, COSV100275285; called by muse, mutect2, varscan2
- OR8J1 | c.877C>A p.L293M | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs766125912, COSV100275287; called by muse, mutect2, varscan2
- OTOF | c.545G>T p.G182V | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.843); catalogued as COSV99719302; called by muse, mutect2, varscan2
- PAF1 | c.1529C>T p.S510L | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as rs778486153, COSV99656104; called by muse, mutect2, varscan2
- PCDHA4 | c.2284G>T p.E762* | Nonsense Mutation (SNP) | VAF 24/152 reads (16%) | catalogued as COSV100793835, COSV63539889; called by muse, mutect2, varscan2
- PCDHAC1 | c.485G>T p.S162I | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.06); catalogued as COSV99170183; called by muse, mutect2, varscan2
- PCDHGA11 | c.855G>T p.M285I | Missense Mutation (SNP) | VAF 38/226 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV99549041; called by muse, mutect2, varscan2
- PDPR | c.569A>C p.D190A | Missense Mutation (SNP) | VAF 40/494 reads (8%) | SIFT tolerated (0.92); PolyPhen benign (0.122); catalogued as COSV99848993; called by muse, mutect2
- PENK | c.460T>A p.S154T | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as COSV100152522; called by muse, mutect2, varscan2
- PGK2 | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 48/141 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.217); catalogued as COSV100505749; called by muse, mutect2, varscan2
- PHACTR3 | c.1106A>G p.N369S | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs755938563, COSV100733309; called by muse, mutect2, varscan2
- PIK3CG | c.274G>T p.G92* | Nonsense Mutation (SNP) | VAF 13/74 reads (18%) | catalogued as COSV100783275; called by muse, mutect2, varscan2
- PKHD1 | c.5726G>T p.R1909L | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.149); catalogued as COSV100584874, COSV61866686; called by muse, mutect2, varscan2
- PLEK | c.399G>T p.M133I | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV99311303; called by muse, mutect2, varscan2
- POU4F2 | c.433A>C p.M145L | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.147); catalogued as COSV99850895; called by muse, mutect2, varscan2
- PRDM9 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as COSV57002253, COSV57005862; called by muse, mutect2, varscan2
- RALGPS1 | c.757A>T p.T253S | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV99402790; called by muse, mutect2, varscan2
- RBPJ | c.973G>T p.G325C | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100623821; called by muse, mutect2, varscan2
- RELN | c.367C>A p.Q123K | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV100635129; called by muse, mutect2, varscan2
- RIMS2 | c.1570G>T p.E524* (on ENST00000666250 / NM_001348490.2; = p.E332* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 17/66 reads (26%) | catalogued as COSV99199969, COSV99212417; called by muse, mutect2, varscan2
- ROBO2 | c.2873C>T p.P958L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.031); catalogued as rs769331626, COSV100170563; called by muse, mutect2, varscan2
- RYR2 | c.490C>A p.P164T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs764772142, CM043074, COSV100773274; called by muse, mutect2, varscan2
- SAXO1 | c.422-2A>T p.X141_splice | Splice Site (SNP) | VAF 26/61 reads (43%) | catalogued as COSV101000216; called by muse, mutect2, varscan2
- SCGN | c.464G>A p.G155D | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100618892; called by muse, mutect2, varscan2
- SFMBT2 | c.1580G>T p.C527F | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.335); catalogued as rs756367475, COSV100739767; called by muse, mutect2, varscan2
- SKI | c.475G>C p.E159Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV101049680; called by muse, mutect2, varscan2
- SLC8B1 | c.191G>T p.R64L | Missense Mutation (SNP) | VAF 36/262 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); catalogued as COSV52527510, COSV99176857; called by muse, mutect2, varscan2
- SLCO6A1 | c.183C>A p.F61L | Missense Mutation (SNP) | VAF 45/317 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV101135161, COSV65811595; called by muse, mutect2, varscan2
- SMPD4 | c.310G>T p.G104C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100302874; called by muse, mutect2, varscan2
- SMYD1 | c.561G>T p.Q187H | Missense Mutation (SNP) | VAF 33/215 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV101352548; called by muse, mutect2, varscan2
- SNRPA | c.562C>G p.Q188E | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.047); catalogued as COSV54681672, COSV99698993; called by muse, mutect2, varscan2
- SORCS3 | c.3259G>T p.A1087S | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as rs1441560618, COSV100865722; called by muse, mutect2, varscan2
- SPEG | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs747013678, COSV100405886; called by muse, mutect2, varscan2
- SPEG | c.5558G>T p.W1853L | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100405887; called by muse, mutect2, varscan2
- SPOCK3 | c.950G>A p.C317Y | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100694261; called by muse, mutect2, varscan2
- SSBP3 | c.476G>T p.G159V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100486722; called by muse, mutect2, varscan2
- SSTR5 | c.830C>A p.P277H | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV99559944; called by muse, mutect2, varscan2
- SURF1 | c.207C>G p.I69M | Missense Mutation (SNP) | VAF 49/246 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV100034893; called by muse, mutect2, varscan2
- SVEP1 | c.10054T>G p.C3352G | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99930047; called by muse, mutect2, varscan2
- SYCE1 | c.160G>C p.E54Q (on ENST00000343131 / NM_001143764.3; = p.E18Q on NM_130784.3) | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs756386589, COSV100385989; called by muse, mutect2, varscan2
- SZT2 | c.3512G>T p.G1171V (on ENST00000634258 / NM_001365999.1; = p.G1114V on NM_015284.4) | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.137); catalogued as COSV100987725; called by muse, mutect2, varscan2
- TAS2R10 | c.203A>G p.Q68R | Missense Mutation (SNP) | VAF 62/111 reads (56%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs754929198, COSV99555664; called by muse, mutect2, varscan2
- TMEM201 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs374807854; called by muse, mutect2
- TMEM245 | c.2595G>T p.R865= | Splice Region (SNP) | VAF 16/78 reads (21%) | catalogued as COSV101002488; called by muse, mutect2, varscan2
- TMEM26 | c.1082C>T p.S361F | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.233); catalogued as COSV53262761; called by muse, mutect2, varscan2
- TMEM63C | c.1217G>T p.W406L | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100029876; called by muse, mutect2, varscan2
- TMEM67 | c.1412+1G>T p.X471_splice | Splice Site (SNP) | VAF 24/77 reads (31%) | catalogued as COSV100020071; called by muse, mutect2, varscan2
- TMPRSS11D | c.264C>A p.F88L | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.04); catalogued as COSV99385110; called by muse, mutect2, varscan2
- TNS1 | c.778C>G p.R260G | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50697321, COSV99412224; called by muse, mutect2, varscan2
- TNS3 | c.1446G>T p.M482I | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV100236670; called by muse, mutect2, varscan2
- TNXB | c.4892C>A p.S1631Y (on ENST00000647633; = p.S1384Y on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100926758, COSV64475243; called by muse, mutect2, varscan2
- TRIM51 | c.1032G>T p.E344D | Missense Mutation (SNP) | VAF 23/157 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99793284; called by muse, mutect2, varscan2
- TTI1 | c.2830C>T p.L944F | Missense Mutation (SNP) | VAF 23/155 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV65064407; called by muse, mutect2, varscan2
- TTN | c.70420C>T p.P23474S (on ENST00000591111; = p.P16050S on NM_003319.4) | Missense Mutation (SNP) | VAF 21/139 reads (15%) | PolyPhen benign (0.23); catalogued as COSV100634663; called by muse, mutect2, varscan2
- TUBA3C | c.191G>A p.R64K | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.874); catalogued as COSV101262854; called by muse, mutect2, varscan2
- UBASH3A | c.1116C>A p.S372R | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.045); catalogued as COSV99370072; called by muse, mutect2, varscan2
- UBQLN3 | c.786G>T p.M262I | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV100294025; called by muse, mutect2, varscan2
- UTP15 | c.1150A>T p.T384S | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99707766; called by muse, mutect2, varscan2
- WFS1 | c.2069G>T p.C690F | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99901418, COSV99901688; called by muse, mutect2, varscan2
- ZFPM2 | c.1659T>A p.C553* | Nonsense Mutation (SNP) | VAF 39/157 reads (25%) | catalogued as COSV101023687; called by muse, mutect2, varscan2
- ZP4 | c.1550T>G p.I517S | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV100850804; called by muse, mutect2, varscan2
- ZPLD1 | c.199G>T p.D67Y (on ENST00000466937 / NM_001329788.1; = p.D83Y on NM_175056.2) | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.972); catalogued as COSV100083647; called by mutect2, varscan2
- ZPLD1 | c.200A>T p.D67V (on ENST00000466937 / NM_001329788.1; = p.D83V on NM_175056.2) | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.764); catalogued as COSV60352197; called by mutect2, varscan2
- ZSCAN9 | c.144G>T p.R48S | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV99356612; called by muse, mutect2, varscan2
- ADAM32 | c.895_905del p.Y299Sfs*30 | Frame Shift Del (DEL) | VAF 10/104 reads (10%) | called by mutect2, pindel
- CDHR1 | c.1277C>A p.S426* | Nonsense Mutation (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- CFC1 | c.208C>A p.P70T | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- CLPSL2 | c.123_124insGC p.S42Afs*22 | Frame Shift Ins (INS) | VAF 12/107 reads (11%) | called by mutect2, varscan2
- DIS3L | c.2084del p.K695Rfs*37 (on ENST00000319212 / NM_001143688.3; = p.K612Rfs*37 on NM_133375.5 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 47/148 reads (32%) | called by mutect2, pindel, varscan2
- FAM214B | c.164del p.P55Lfs*12 | Frame Shift Del (DEL) | VAF 15/44 reads (34%) | called by mutect2, pindel, varscan2
- GPR158 | c.2419del p.L807* | Frame Shift Del (DEL) | VAF 41/192 reads (21%) | called by mutect2, pindel, varscan2
- LRRC4C | c.504del p.F168Lfs*10 | Frame Shift Del (DEL) | VAF 8/88 reads (9%) | called by mutect2, pindel
- NACC2 | c.179G>T p.S60I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by mutect2, varscan2
- OR52B2 | c.509del p.F170Sfs*3 | Frame Shift Del (DEL) | VAF 9/49 reads (18%) | called by mutect2, pindel, varscan2
- TNXB | c.9945del p.T3316Qfs*58 (on ENST00000647633; = p.T3069Qfs*58 on NM_019105.8 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 26/173 reads (15%) | called by mutect2, pindel, varscan2
- TXNIP | c.857dup p.K287Efs*5 | Frame Shift Ins (INS) | VAF 23/147 reads (16%) | called by mutect2, pindel, varscan2
- ZFR | c.672_677del p.F225_S226del | In Frame Del (DEL) | VAF 9/79 reads (11%) | called by mutect2, pindel, varscan2
- ACIN1 | c.2691C>A p.I897= | Silent (SNP) | VAF 25/140 reads (18%) | catalogued as COSV99400508; called by muse, mutect2, varscan2
- ACTRT3 | c.153C>G p.L51= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as COSV100377605; called by muse, mutect2
- ADGRG6 | c.780T>G p.S260= | Silent (SNP) | VAF 35/84 reads (42%) | catalogued as COSV99749267; called by muse, mutect2, varscan2
- ANGEL1 | c.1146G>T p.S382= | Silent (SNP) | VAF 21/141 reads (15%) | catalogued as rs756273323, COSV99200515; called by muse, mutect2, varscan2
- APOB | c.5163C>T p.V1721= | Silent (SNP) | VAF 64/341 reads (19%) | catalogued as rs536182427, COSV51925317; called by muse, mutect2, varscan2
- ASPHD1 | c.817C>A p.R273= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as rs778935959, COSV100435973, COSV58103886; called by muse, mutect2, varscan2
- CAMK2D | c.69G>T p.G23= | Silent (SNP) | VAF 23/175 reads (13%) | called by muse, mutect2
- CCT8 | c.1347C>T p.P449= | Silent (SNP) | VAF 20/99 reads (20%) | catalogued as rs773410665, COSV99726201; called by muse, mutect2, varscan2
- CDH23 | c.2802C>A p.P934= | Silent (SNP) | VAF 27/140 reads (19%) | catalogued as COSV99824422; called by muse, mutect2, varscan2
- CHD6 | c.1560C>T p.T520= | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as COSV100498775; called by muse, mutect2, varscan2
- CLCA4 | c.2106A>T p.P702= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV99760892; called by muse, mutect2
- CPNE7 | c.709C>A p.R237= | Silent (SNP) | VAF 14/92 reads (15%) | catalogued as COSV99255208; called by muse, mutect2, varscan2
- DGKD | c.2052G>T p.P684= (on ENST00000264057 / NM_152879.3; = p.P640= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/180 reads (15%) | catalogued as rs370757617, COSV51047421, COSV99897866; called by muse, mutect2, varscan2
- DNAJC13 | c.2169G>A p.L723= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as COSV99608365; called by muse, mutect2, varscan2
- EIF1 | c.315C>T p.D105= | Silent (SNP) | VAF 16/117 reads (14%) | catalogued as rs3386; called by muse, mutect2, varscan2
- EXT2 | c.1023G>T p.P341= (on ENST00000343631; = p.P374= on NM_000401.3) | Silent (SNP) | VAF 34/201 reads (17%) | catalogued as COSV100640710; called by muse, mutect2, varscan2
- F5 | c.1047G>A p.R349= | Silent (SNP) | VAF 31/137 reads (23%) | catalogued as COSV100889290; called by muse, mutect2, varscan2
- FERD3L | c.462C>A p.T154= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV51761524; called by muse, mutect2, varscan2
- GFAP | c.69G>T p.G23= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV99493713; called by muse, mutect2, varscan2
- GLT1D1 | c.870C>A p.S290= (on ENST00000442111 / NM_001366889.1; = p.S210= on NM_144669.3) | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV99897856; called by muse, mutect2, varscan2
- GNAS | c.1737C>T p.D579= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs1175227356, COSV100007984; called by muse, mutect2, varscan2
- GTSF1 | c.255C>A p.T85= | Silent (SNP) | VAF 32/136 reads (24%) | catalogued as COSV100007562; called by muse, mutect2, varscan2
- HAP1 | c.1989G>T p.R663= (on ENST00000310778 / NM_001367460.1; = p.R611= on NM_177977.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/196 reads (18%) | catalogued as COSV100170092; called by muse, mutect2, varscan2
- HMGB4 | c.477C>G p.L159= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as COSV53885871; called by muse, mutect2, varscan2
- IFITM3 | c.36C>T p.V12= | Silent (SNP) | VAF 40/218 reads (18%) | catalogued as COSV101296809; called by muse, varscan2
- KDR | c.3045C>G p.G1015= | Silent (SNP) | VAF 21/92 reads (23%) | catalogued as COSV99818919; called by muse, mutect2, varscan2
- KIF27 | c.945C>T p.I315= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as COSV99927364; called by muse, mutect2, varscan2
- LEP | c.111A>T p.T37= | Silent (SNP) | VAF 51/231 reads (22%) | catalogued as COSV100451480; called by muse, mutect2, varscan2
- LMOD1 | c.480G>A p.K160= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as COSV100939298; called by muse, mutect2, varscan2
- LRRC23 | c.222G>A p.L74= | Silent (SNP) | VAF 65/122 reads (53%) | catalogued as COSV99145391; called by muse, mutect2, varscan2
- LVRN | c.2712C>A p.V904= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV100773445, COSV100773713; called by muse, mutect2, varscan2
- MON2 | c.4806C>T p.Y1602= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV99743928; called by muse, mutect2, varscan2
- MUC16 | c.14991C>G p.T4997= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV101202121; called by muse, mutect2, varscan2
- MX1 | c.1095G>T p.P365= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as COSV99912902; called by muse, mutect2, varscan2
- MYH8 | c.2778T>A p.T926= | Silent (SNP) | VAF 61/287 reads (21%) | catalogued as COSV101238976; called by muse, mutect2, varscan2
- NRG2 | c.801C>A p.S267= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV99183535; called by muse, mutect2, varscan2
- NTNG1 | c.402C>A p.I134= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as COSV99640079; called by muse, mutect2, varscan2
- NUMBL | c.492G>T p.G164= | Silent (SNP) | VAF 100/242 reads (41%) | catalogued as rs781186421, COSV99425180; called by muse, mutect2, varscan2
- OR8D1 | c.849C>A p.P283= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs141412375, COSV100766686; called by muse, mutect2
- PALM2AKAP2 | c.582C>T p.H194= (on ENST00000374531 / NM_001037293.2; = p.H226= on NM_053016.6) | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as COSV100093823; called by muse, mutect2, varscan2
- PCDHGB1 | c.726G>A p.E242= | Silent (SNP) | VAF 20/129 reads (16%) | catalogued as COSV99549037; called by muse, mutect2, varscan2
- POF1B | c.57C>A p.L19= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99427618; called by muse, mutect2, varscan2
- POM121L12 | c.366G>T p.G122= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV101374976, COSV101375003; called by muse, mutect2
- PROM1 | c.831G>A p.L277= | Silent (SNP) | VAF 3/26 reads (12%) | catalogued as COSV101477147; called by muse, mutect2
- RALGAPA1 | c.2514G>C p.L838= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV99356508; called by muse, mutect2
- RALGAPA2 | c.3252C>T p.A1084= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as rs762230375, COSV52490703; called by muse, mutect2, varscan2
- RGS6 | c.189T>A p.T63= | Silent (SNP) | VAF 26/125 reads (21%) | catalogued as COSV100667213; called by muse, mutect2, varscan2
- RIMS2 | c.829C>A p.R277= (on ENST00000666250 / NM_001348490.2; = p.R85= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 14/134 reads (10%) | catalogued as COSV51735165, COSV99212402; called by muse, mutect2
- SCN2A | c.4812C>G p.L1604= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV99333953; called by muse, mutect2, varscan2
- SEMA3D | c.618T>A p.S206= | Silent (SNP) | VAF 13/83 reads (16%) | catalogued as COSV99407561; called by muse, mutect2, varscan2
- SSTR3 | c.837C>G p.V279= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as COSV100142934; called by muse, mutect2, varscan2
- SSTR5 | c.831C>A p.P277= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV99559948; called by muse, mutect2, varscan2
- STX1A | c.135C>T p.D45= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV99767621; called by muse, mutect2, varscan2
- STYXL2 | c.3349C>A p.R1117= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99610037; called by muse, mutect2, varscan2
- TRANK1 | c.1896A>T p.T632= | Silent (SNP) | VAF 31/147 reads (21%) | catalogued as COSV100085196; called by muse, mutect2, varscan2
- UBR4 | c.4560C>T p.P1520= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as rs764524117, COSV100922128; called by muse, mutect2, varscan2
- VCAN | c.9583C>A p.R3195= | Silent (SNP) | VAF 20/178 reads (11%) | catalogued as COSV99427716; called by muse, mutect2, varscan2
- WRAP73 | c.312C>T p.R104= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV99573575; called by muse, mutect2, varscan2
- ZFP57 | c.975A>T p.P325= | Silent (SNP) | VAF 31/226 reads (14%) | catalogued as COSV100971993; called by muse, mutect2, varscan2
- ZFPM2 | c.2721C>A p.V907= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV101023689; called by muse, mutect2, varscan2
- ZFYVE28 | c.1587T>G p.S529= | Silent (SNP) | VAF 12/95 reads (13%) | catalogued as COSV99343852; called by muse, mutect2, varscan2
- ZNF2 | c.1308A>C p.G436= (on ENST00000611147 / NM_001291605.2; = p.G423= on NM_021088.4) | Silent (SNP) | VAF 18/108 reads (17%) | catalogued as COSV99728758; called by muse, mutect2, varscan2
- AC244258.1 | n.895C>T | RNA (SNP) | VAF 34/118 reads (29%) | called by muse, mutect2, varscan2
- CEP295 | chr11:93735197 A>G | 3'Flank (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- CR1 | c.487+12317T>A | Intron (SNP) | VAF 31/145 reads (21%) | catalogued as COSV100888097; called by muse, mutect2, varscan2
- LDB3 | c.896+6753C>T | Intron (SNP) | VAF 22/138 reads (16%) | catalogued as rs121908335, CM050286; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MELTF | c.712+1658C>T | Intron (SNP) | VAF 14/81 reads (17%) | catalogued as COSV99586693; called by muse, mutect2, varscan2
- MIR302F | n.49dup | RNA (INS) | VAF 11/93 reads (12%) | called by mutect2, pindel, varscan2
